TCGA case TCGA-50-5051 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e1c55bac-bb41-4964-add5-ecd6ba04b58d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Dead; Days to death: 478 days (1.3 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 42.7 years (15,585 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 62 days; Days to treatment end: 123 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 71 days; Days to treatment end: 124 days; Treatment dose: 5,490 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 43.2 years (15,769 days); Days to diagnosis: 184 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 184 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 184 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 455 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 478 days (1.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- KRAS mutation, nos: Positive.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 30; Tobacco smoking quit year: 2006.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-50-5051-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-50-5051-01A-02-BS2: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-50-5051-01A-01-BS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-50-5051-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; KRAS mutation found: Yes; KRAS gene analysis indicator: Yes; EGFR mutation status: Yes.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Follow-up form: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 478 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 478 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 184 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-50-5051-01A-21D-1854-01): tumor purity 0.59, ploidy 2.96, whole-genome doublings 1.
